MMRF case MMRF_2384 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/5a283046-afd5-4a09-b557-2cc1830f7ea3

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 57 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 57.2 years (20,882 days); ISS stage: II; Days to last known disease status: 707 days (1.9 years); Days to last follow up: 707 days (1.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 231 days; Days to treatment end: 231 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 2.55 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.957 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 59.7 mg/dL; Immunoglobulin G 4.8 g/L; Immunoglobulin A 12 g/L; Immunoglobulin M 0.43 g/L; Beta 2 Microglobulin 4.4 µg/mL; Lactate Dehydrogenase 5.48 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 3.96 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 303 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.5 mmol/L; Albumin 41 g/L; Total Protein 7.4 g/dL; Glucose 4.62 mmol/L; C-Reactive Protein 1 mg/dL.
- Day 92 (ECOG 1): M Protein 0 g/dL; Lactate Dehydrogenase 6.25 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.19 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 6 g/dL; Glucose 5.01 mmol/L.
- Day 185 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.988 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.85 mg/dL; Immunoglobulin G 4.2 g/L; Immunoglobulin A 0.83 g/L; Immunoglobulin M 0.65 g/L; Beta 2 Microglobulin 1.6 µg/mL; Lactate Dehydrogenase 7.22 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 3.58 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 299 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 44 g/L; Total Protein 6.2 g/dL; Glucose 5.12 mmol/L.
- Day 259: Lactate Dehydrogenase 8.08 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 4.11 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 110 ×10⁹/L; Creatinine 55.7 µmol/L; Calcium 2.33 mmol/L; Albumin 44 g/L; Total Protein 6.2 g/dL; Glucose 5.06 mmol/L.
- Day 337: Lactate Dehydrogenase 5.45 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.56 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 53.9 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.45 mmol/L; Albumin 43 g/L; Total Protein 6 g/dL; Glucose 5.01 mmol/L.
- Day 449: Lactate Dehydrogenase 6.35 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 3.52 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 227 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 5.7 g/dL; Glucose 2.75 mmol/L.
- Day 534: Serum Free Immunoglobulin Light Chain, Kappa 1.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.29 mg/dL; Lactate Dehydrogenase 7.32 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 4.34 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.48 mmol/L; Albumin 41 g/L; Total Protein 6.1 g/dL; Glucose 4.51 mmol/L.
- Day 618: Immunoglobulin G 5.2 g/L; Immunoglobulin A 0.48 g/L; Immunoglobulin M 0.85 g/L; Lactate Dehydrogenase 6 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 3.95 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL; Glucose 4.35 mmol/L.
- Day 707 (ECOG 0): M Protein 6.52 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.23 mg/dL; Immunoglobulin A 2.5 g/L; Immunoglobulin M 1 g/L; Lactate Dehydrogenase 6.48 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 4.52 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 263 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 5.12 mmol/L.

Other clinical attributes
- Day 1: Weight: 50 kg; Height: 156 cm.

Biospecimens (2 samples)
- Sample MMRF_2384_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2384_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
